Somatic mutation profile of tumor specimen TCGA-AY-4070-01A (aliquot TCGA-AY-4070-01A-01W-1073-09) from TCGA case TCGA-AY-4070, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 51.0 years (18,621 days).
Specimen TCGA-AY-4070-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cad0d62b-68ea-4cdd-b7c4-63d1cfd60779.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AY-4070-10A (Blood Derived Normal), aliquot TCGA-AY-4070-10A-01W-1073-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c4893b3-ecbf-4c66-ac90-e33df87936ae

The open-access MAF lists 154 somatic variants for this specimen: 115 protein-altering or splice-affecting, 38 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 104, Silent 38, Splice Site 4, Frame Shift Ins 2, In Frame Del 1, Frame Shift Del 1, In Frame Ins 1, Nonsense Mutation 1, Intron 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.1637G>T p.G546V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28942081, CM074918, CM900157, COSV99369536; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 13/110 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2
- ABHD12B | c.511G>A p.V171I (on ENST00000337334 / NM_001206673.2; = p.V94I on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.806); catalogued as rs941054124, COSV61569603; called by muse, mutect2, varscan2
- ADAM17 | c.989C>G p.S330C | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV100176028; called by muse, mutect2
- ADAM2 | c.1918T>G p.L640V | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.05); catalogued as COSV55863173; called by muse, mutect2, varscan2
- ADAM9 | c.2159G>T p.R720M | Missense Mutation (SNP) | VAF 16/274 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101166003; called by muse, mutect2
- AKR1C2 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 18/184 reads (10%) | catalogued as COSV66333288; called by muse, mutect2
- ALMS1 | c.8941A>G p.N2981D | Missense Mutation (SNP) | VAF 180/584 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV52511485; called by muse, mutect2, varscan2
- ARMC2 | c.2552G>C p.R851P | Missense Mutation (SNP) | VAF 25/298 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64550311, COSV64551406; called by muse, mutect2
- ASAP1 | c.3238G>A p.A1080T | Missense Mutation (SNP) | VAF 29/427 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100726833; called by muse, mutect2
- ATG2A | c.1003A>C p.N335H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV65967081; called by muse, mutect2
- ATR | c.5830C>T p.L1944F | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63386947, COSV63387161, COSV63391824; called by muse, mutect2, varscan2
- CACNG5 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201783473; called by muse, mutect2, varscan2
- CCDC30 | c.1955G>A p.R652H (on ENST00000340612; = p.R609H on NM_001080850.3) | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as rs190370892, COSV59606929; called by muse, mutect2, varscan2
- CDHR3 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100487979; called by muse, mutect2
- CDNF | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 27/173 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65805881; called by muse, mutect2, varscan2
- CHORDC1 | c.492+1G>T p.X164_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100271849; called by muse, mutect2, varscan2
- CHST10 | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 11/300 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99958691; called by muse, mutect2
- CLCA2 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.654); catalogued as rs1479542832; called by muse, mutect2
- CLEC6A | c.305A>T p.K102M | Missense Mutation (SNP) | VAF 45/184 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV65987406; called by muse, mutect2, varscan2
- CNTN6 | c.2089G>T p.A697S | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV63174507, COSV63184172; called by muse, mutect2, varscan2
- CYP3A5 | c.1313C>A p.P438H | Missense Mutation (SNP) | VAF 197/709 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56119666, COSV56120379; called by muse, mutect2, varscan2
- DARS2 | c.1409T>G p.L470R | Missense Mutation (SNP) | VAF 13/306 reads (4%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as COSV53407307; called by muse, mutect2
- DISP3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs756856438, COSV53828906; called by muse, mutect2
- DNAH10 | c.11279G>A p.R3760H (on ENST00000409039; = p.R3699H on NM_207437.3) | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1327635542, COSV68994934; called by muse, mutect2, varscan2
- DOCK4 | c.4469G>C p.C1490S | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.636); catalogued as COSV70237706; called by muse, mutect2
- EMB | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.238); catalogued as COSV57482523; called by muse, mutect2, varscan2
- EXOC2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 28/151 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV57865810; called by muse, mutect2, varscan2
- FIP1L1 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.981); catalogued as COSV60996960; called by muse, mutect2, varscan2
- FOSL1 | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.335); catalogued as COSV100440811, COSV57027523; called by muse, mutect2
- GART | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs767062634, COSV63113884; called by muse, mutect2, varscan2
- GPKOW | c.1280G>A p.G427D | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50242932; called by muse, mutect2, varscan2
- GRIK5 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.052); catalogued as COSV53479255; called by muse, mutect2, varscan2
- GRIN3A | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 64/237 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs375779429, COSV62451129; called by muse, mutect2, varscan2
- HSPB9 | c.280A>T p.S94C | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV56791178; called by muse, mutect2
- HUWE1 | c.4969_4970insT p.R1657Mfs*13 | Frame Shift Ins (INS) | VAF 26/143 reads (18%) | catalogued as COSV99470606; called by mutect2, pindel, varscan2
- IQCB1 | c.1304G>A p.R435H | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.976); catalogued as rs146832128, COSV60437015; called by muse, mutect2, varscan2
- IQGAP2 | c.1772C>A p.S591Y | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV99166704; called by muse, mutect2
- ITGAV | c.142T>A p.Y48N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV53713565; called by muse, mutect2, varscan2
- JADE3 | c.1591T>A p.S531T | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99509535; called by muse, mutect2
- KCTD18 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV100728812, COSV63344490; called by muse, mutect2, varscan2
- KLHL4 | c.255G>T p.Q85H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV100909706, COSV64143196, COSV64146937; called by muse, mutect2, varscan2
- KRBOX4 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV53343959, COSV99994173; called by muse, mutect2
- KRTAP3-2 | c.296G>C p.*99Sext*32 | Nonstop Mutation (SNP) | VAF 9/52 reads (17%) | catalogued as COSV101196003; called by muse, mutect2, varscan2
- KSR2 | c.1225A>G p.N409D | Missense Mutation (SNP) | VAF 57/171 reads (33%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.593); catalogued as COSV56674365; called by muse, mutect2, varscan2
- LAMA3 | c.9832C>A p.P3278T (on ENST00000313654 / NM_198129.4; = p.P1669T on NM_000227.6) | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99333926; called by muse, mutect2
- LAMA4 | c.5381G>A p.R1794H (on ENST00000230538 / NM_001105206.3; = p.R1787H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782780328, COSV57900553, COSV57902994; called by muse, mutect2
- LRRFIP1 | c.1598C>T p.T533I (on ENST00000392000 / NM_001137552.2; = p.T509I on NM_004735.4) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV55252485; called by muse, mutect2, varscan2
- MAN2A2 | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751201650, COSV100847750; called by muse, mutect2
- MICU3 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs774411224, COSV58846486; called by muse, mutect2, varscan2
- MOCS3 | c.319G>C p.G107R | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54866584; called by muse, varscan2
- MPP5 | c.304C>G p.P102A | Missense Mutation (SNP) | VAF 8/169 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.219); catalogued as COSV99906728; called by muse, mutect2
- MUC17 | c.4606A>G p.T1536A | Missense Mutation (SNP) | VAF 12/268 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.213); catalogued as COSV100071603; called by muse, mutect2
- NBEA | c.3411A>T p.E1137D | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0); catalogued as COSV59789798; called by muse, mutect2, varscan2
- NBR1 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 42/320 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100357678, COSV57834081; called by muse, mutect2, varscan2
- NDUFS2 | c.289C>A p.L97I | Missense Mutation (SNP) | VAF 8/151 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV100917334; called by muse, mutect2
- NID2 | c.1553G>A p.G518E | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53497348; called by muse, mutect2, varscan2
- NPTX1 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.365); catalogued as rs1419329694, COSV60775236; called by muse, mutect2
- NRK | c.3283G>A p.A1095T | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV54598859; called by muse, mutect2
- OR2K2 | c.274C>A p.L92I (on ENST00000374428; = p.L63I on NM_205859.2) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV57017212; called by muse, mutect2, varscan2
- OR4A47 | c.395T>G p.V132G | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV71445011, COSV71445038; called by muse, mutect2
- OR4F6 | c.59C>T p.S20L | Missense Mutation (SNP) | VAF 216/499 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as rs776041979, COSV61026936; called by muse, mutect2, varscan2
- OR4S1 | c.209G>T p.C70F | Missense Mutation (SNP) | VAF 130/345 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV60679219; called by muse, mutect2, varscan2
- OR52R1 | c.430G>C p.V144L | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61888565, COSV61889247; called by muse, mutect2
- PAF1 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99655584; called by muse, mutect2
- PAGE1 | c.352G>A p.G118R | Missense Mutation (SNP) | VAF 21/351 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs782020946, COSV65998232; called by muse, mutect2
- PCDHA3 | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.604); catalogued as rs573377233, COSV63539565; called by muse, mutect2, varscan2
- PCDHGA10 | c.46G>A p.G16R | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as rs1384304697, COSV53961645; called by muse, mutect2, varscan2
- PCDHGA9 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 95/216 reads (44%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.444); catalogued as rs781611924, COSV53961638; called by muse, mutect2, varscan2
- PEG3 | c.3158A>T p.Y1053F | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.757); catalogued as COSV55625863, COSV55635862; called by muse, mutect2, varscan2
- PKHD1 | c.5185G>T p.A1729S | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV61895863; called by muse, mutect2
- PLCD1 | c.2092G>A p.A698T | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs761355914, COSV99378418; called by muse, mutect2, varscan2
- PLTP | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV62464996; called by muse, mutect2, varscan2
- PTRHD1 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53230798; called by muse, mutect2, varscan2
- RAB31 | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs760965574, COSV71261705; called by muse, mutect2, varscan2
- RGL4 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.811); catalogued as COSV51944080; called by muse, mutect2, varscan2
- RNF43 | c.252+1G>A p.X84_splice | Splice Site (SNP) | VAF 18/105 reads (17%) | catalogued as COSV60414944, COSV60417440; called by muse, mutect2, varscan2
- RTL4 | c.437C>A p.P146H | Missense Mutation (SNP) | VAF 24/515 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.554); catalogued as COSV100465722, COSV61206926, COSV61207477; called by muse, mutect2
- RUBCN | c.2647-1G>T p.X883_splice | Splice Site (SNP) | VAF 45/263 reads (17%) | catalogued as COSV99583199; called by muse, mutect2, varscan2
- RYR2 | c.14774T>C p.L4925P | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63666705; called by muse, mutect2, varscan2
- SCAMP3 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV56945504; called by muse, mutect2, varscan2
- SCIN | c.2118G>C p.W706C (on ENST00000297029 / NM_001112706.3; = p.W459C on NM_033128.3) | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368365557, COSV51689106, COSV51693585; called by muse, mutect2, varscan2
- SETDB1 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.097); catalogued as COSV99643771; called by muse, mutect2
- SLC24A2 | c.1562C>T p.A521V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1275622190, COSV53864937; called by muse, mutect2
- SLF2 | c.1727C>A p.A576D | Missense Mutation (SNP) | VAF 10/288 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99488478; called by muse, mutect2
- SPG11 | c.5121+1G>T p.X1707_splice | Splice Site (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99968043; called by muse, mutect2
- SPINK5 | c.3095T>A p.L1032Q | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99806116; called by muse, mutect2
- TAB2 | c.333A>T p.Q111H | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99644512; called by muse, mutect2
- TANC1 | c.1597C>A p.H533N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.065); catalogued as COSV55088860, COSV99713087; called by muse, mutect2
- TEX9 | c.691A>C p.N231H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.717); catalogued as COSV61878605; called by muse, mutect2, varscan2
- TG | c.6196C>T p.P2066S | Missense Mutation (SNP) | VAF 35/247 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.32); catalogued as COSV55079110; called by muse, mutect2, varscan2
- THBS2 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765238898, COSV64678324; called by muse, mutect2, varscan2
- TINAG | c.95A>C p.E32A | Missense Mutation (SNP) | VAF 36/435 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV52510390; called by muse, mutect2
- TLL1 | c.2750G>T p.C917F | Missense Mutation (SNP) | VAF 105/201 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50288984; called by muse, mutect2, varscan2
- TPP1 | c.442A>G p.T148A | Missense Mutation (SNP) | VAF 90/125 reads (72%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV54994325; called by muse, mutect2, varscan2
- TRDJ2 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 51/191 reads (27%) | catalogued as rs372451495; called by muse, mutect2, varscan2
- TRPV6 | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); catalogued as rs751323691, COSV63892034; called by muse, mutect2
- TTC14 | c.1015_1018del p.Q339Tfs*6 | Frame Shift Del (DEL) | VAF 12/74 reads (16%) | catalogued as rs750626950; called by pindel, varscan2
- TTC30A | c.1934C>G p.T645R | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1280602840, COSV63101575; called by muse, mutect2
- TUBA3E | c.1262C>A p.A421D | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.836); catalogued as COSV99919631; called by muse, mutect2
- UGGT2 | c.3993T>G p.F1331L | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65075381; called by muse, mutect2, varscan2
- UGT1A1 | c.992A>C p.Q331P | Missense Mutation (SNP) | VAF 28/281 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM930723, COSV59390020; called by muse, mutect2, varscan2
- VANGL2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs754493544, COSV63604611; called by muse, mutect2, varscan2
- WDPCP | c.1919T>C p.L640P | Missense Mutation (SNP) | VAF 8/142 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.927); catalogued as COSV99703993; called by muse, mutect2
- ZBTB25 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67198659; called by muse, mutect2, varscan2
- ZCCHC14 | c.794C>T p.A265V (on ENST00000268616; = p.A402V on NM_015144.3) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs745846476, COSV51886758; called by muse, mutect2, varscan2
- ZNF213 | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV67727852; called by muse, mutect2, varscan2
- ZNF589 | c.992C>G p.S331W | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61220318, COSV61220487; called by muse, mutect2, varscan2
- OR3A3 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- POU5F1 | c.307dup p.V103Gfs*86 | Frame Shift Ins (INS) | VAF 10/80 reads (13%) | called by mutect2, pindel
- RIF1 | c.2649_2651del p.N883del | In Frame Del (DEL) | VAF 13/51 reads (25%) | called by pindel, varscan2
- SEMA4G | c.2038G>A p.A680T (on ENST00000370250; = p.A685T on NM_017893.3) | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2
- SLIT2 | c.244_245insAAAAAAAAA p.L81_R82insKKK | In Frame Ins (INS) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- TRBV24-1 | c.176G>T p.G59V | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2
- ZNF496 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.42); PolyPhen benign (0.28); called by muse, mutect2
- ADAMTS1 | c.1323G>A p.Q441= | Silent (SNP) | VAF 71/111 reads (64%) | catalogued as COSV53170867; called by muse, mutect2, varscan2
- AL592490.1 | c.1356G>A p.A452= | Silent (SNP) | VAF 29/277 reads (10%) | catalogued as rs777755843, COSV69426569; called by muse, mutect2, varscan2
- ARFGEF3 | c.2100G>T p.L700= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as COSV99292341; called by muse, mutect2
- BAIAP2L2 | c.418C>T p.L140= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60202066; called by muse, mutect2, varscan2
- CALCRL | c.1212C>A p.I404= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV66475336; called by muse, mutect2, varscan2
- CAMTA1 | c.2013C>T p.S671= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV100346284; called by muse, mutect2
- CCDC144A | c.2925T>A p.A975= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100138331; called by mutect2, varscan2
- CIDEB | c.66G>A p.E22= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV51866050, COSV51867896; called by muse, mutect2, varscan2
- CLCC1 | c.1146G>A p.Q382= (on ENST00000356970 / NM_001377464.1; = p.Q332= on NM_015127.5) | Silent (SNP) | VAF 60/169 reads (36%) | catalogued as COSV56763641; called by muse, mutect2, varscan2
- DIS3 | c.1518T>A p.I506= | Silent (SNP) | VAF 12/145 reads (8%) | catalogued as COSV66706748; called by muse, mutect2
- EOLA1 | c.453G>T p.L151= | Silent (SNP) | VAF 13/123 reads (11%) | catalogued as COSV63734132; called by muse, mutect2, varscan2
- ESYT3 | c.2455C>T p.L819= | Silent (SNP) | VAF 150/203 reads (74%) | catalogued as COSV67440521, COSV67441060; called by muse, mutect2, varscan2
- FEM1B | c.1863A>G p.E621= | Silent (SNP) | VAF 50/88 reads (57%) | catalogued as COSV60988665; called by muse, mutect2, varscan2
- FNDC3B | c.1869G>T p.V623= | Silent (SNP) | VAF 12/236 reads (5%) | catalogued as COSV100393600; called by muse, mutect2
- GNA12 | c.663C>T p.I221= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as COSV99282317; called by muse, mutect2, varscan2
- GRK1 | c.204C>T p.G68= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as COSV59552991; called by muse, mutect2, varscan2
- IL17RE | c.25C>T p.L9= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV55968732; called by muse, mutect2, varscan2
- KL | c.1872C>T p.S624= | Silent (SNP) | VAF 49/426 reads (12%) | catalogued as rs772097707, COSV66308971; called by muse, mutect2, varscan2
- KLHL10 | c.588T>C p.N196= | Silent (SNP) | VAF 17/145 reads (12%) | catalogued as COSV53173422; called by muse, mutect2, varscan2
- LAMB1 | c.2643G>T p.G881= | Silent (SNP) | VAF 40/534 reads (7%) | catalogued as COSV55965392; called by muse, mutect2
- MAP2 | c.279G>A p.R93= | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as COSV52293376; called by muse, mutect2
- MARCO | c.609G>A p.E203= | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV59051496; called by muse, mutect2
- MGAM | c.3792T>C p.D1264= | Silent (SNP) | VAF 94/293 reads (32%) | catalogued as COSV72074776; called by muse, mutect2, varscan2
- MICALL1 | c.258C>G p.V86= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99317007; called by muse, mutect2
- MYH7 | c.2997G>T p.L999= | Silent (SNP) | VAF 40/201 reads (20%) | catalogued as COSV62519955; called by muse, mutect2, varscan2
- OR10A6 | c.597A>C p.A199= | Silent (SNP) | VAF 33/147 reads (22%) | catalogued as COSV59165050; called by muse, mutect2, varscan2
- OTUD7B | c.2193C>A p.P731= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV64916363; called by muse, mutect2
- PLA1A | c.1320C>T p.N440= | Silent (SNP) | VAF 16/135 reads (12%) | catalogued as COSV56332066; called by muse, mutect2, varscan2
- PMEPA1 | c.552C>T p.R184= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1237005481, COSV55692848; called by muse, mutect2, varscan2
- POU4F1 | c.1251C>A p.A417= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV65884416; called by muse, mutect2
- RASSF9 | c.654C>T p.F218= | Silent (SNP) | VAF 25/281 reads (9%) | catalogued as COSV63433271, COSV63434933; called by muse, mutect2
- SCN4A | c.4419C>T p.F1473= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as rs374319193; ClinVar: likely benign; called by muse, mutect2, varscan2
- SIX2 | c.753C>A p.G251= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV57391051; called by muse, mutect2, varscan2
- SVIL | c.1923C>T p.R641= | Silent (SNP) | VAF 26/319 reads (8%) | catalogued as COSV100880906; called by muse, mutect2
- THSD7B | c.1281G>A p.T427= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs563732139, COSV55693111, COSV99760095; called by muse, mutect2, varscan2
- TNN | c.1950C>T p.Y650= | Silent (SNP) | VAF 63/167 reads (38%) | catalogued as rs759866598, COSV53420837; called by muse, mutect2, varscan2
- XAB2 | c.1584G>A p.L528= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV99349854; called by muse, mutect2
- ZNF354A | c.1290C>A p.I430= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as rs751613551, COSV59983557; called by muse, mutect2
- DHRS4L1 | n.177-423G>C | Intron (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
